Gene-level copy-number profile of tumor specimen ALCH-B3DT-TTP1-A from ALCHEMIST case ALCH-B3DT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,191 days).
Specimen ALCH-B3DT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c59bfd86-d073-494d-8c70-048f6484e214.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,390 have no estimate.
https://portal.gdc.cancer.gov/files/cee84417-5f77-40f7-a2c8-437552a1e892

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 14,016; copy number 2: 37,132; copy number 3: 6,673; copy number 4: 169; copy number 5: 73; copy number 6: 46; copy number 7: 1; copy number 8: 37; copy number 10: 72.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,759,259–94,761,116, 2 genes: CYP4F32P, AC073464.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr12:121,626,550–121,642,677, 1 gene: ORAI1.
- chr16:30,183,505–30,184,957, 1 gene (within-gene range 0–2): AC012645.3.
- chr16:88,706,483–88,715,396, 2 genes (within-gene range 0–2): CTU2, AC138028.6.
- chr16:88,716,278–88,741,425, 3 genes (within-gene range 0–2): MIR4722, AC138028.4, AC138028.2.
- chr22:20,148,416–20,151,055, 1 gene: CCDC188.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 229 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:459,939–1,495,933, 16 genes, copy number 5: B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2.
- chr12:9,852,984–12,289,329, 91 genes, copy number 8–10 (broad region; genes not listed).
- chr12:15,001,787–15,006,999, 1 gene, copy number 7: LINC01489.
- chr12:16,188,485–25,409,445, 121 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
